Somatic mutation profile of tumor specimen TARGET-30-PATNRK-09A (aliquot TARGET-30-PATNRK-09A-01D) from TARGET case TARGET-30-PATNRK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.8 years (1,373 days).
Specimen TARGET-30-PATNRK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07fc0d20-ab7d-474a-851f-87c2b5bdcfb1.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATNRK-10A (Blood Derived Normal), aliquot TARGET-30-PATNRK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c4dc7213-99a3-48c1-8e6f-c540288a4ec1

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.910C>G p.R304G | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as CM087437, CS983483, COSV62192041, COSV62210573; called by muse, mutect2, varscan2
- CCDC8 | c.-190C>G | 5'UTR (SNP) | VAF 32/83 reads (39%) | catalogued as rs1395501325; called by muse, mutect2, varscan2
